Gene-level copy-number profile of tumor specimen TCGA-CV-7177-01A from TCGA case TCGA-CV-7177, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 82.6 years (30,180 days).
Specimen TCGA-CV-7177-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.f2b4d2a2-a3af-4bc3-8b08-8041c4580941.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7177-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b925c627-12cb-437b-b76d-dd6f323762b2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 29; copy number 1: 6,981; copy number 2: 38,626; copy number 3: 10,597; copy number 4: 3,576; copy number 6: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-7177-01A-11D-2010-01): tumor purity 0.63, ploidy 2.1, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 29 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:152,090,459–152,318,364, 7 genes: LINC02273, AC079340.3, AC079340.1, AC079340.2, RN7SL446P, AC080078.1, AC080078.2.
- chr4:152,337,655–152,338,098, 1 gene: FBXW7-AS1.
- chr5:178,184,505–178,590,393, 8 genes (within-gene range 0–1): GMCL2, HNRNPAB, PHYKPL, COL23A1, AC136601.2, AC136601.1, RN7SL646P, AC008659.1.
- chr9:21,802,636–22,128,103, 13 genes (within-gene range 0–1): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:12,243,308–12,381,255, 3 genes, copy number 6: AL109838.1, AL136460.1, PA2G4P2.

Autosomal genes at a single copy (total copy number 1): 6,981. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
